HCMI case HCM-CSHL-0728-C25 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ddba0c54-930d-4dc4-b74f-48e29961c945

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Year of birth: 1965; Vital status: Dead; Days to death: 605 days (1.7 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; ICD-10 code: C25.9; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Head of pancreas; Classification of tumor: primary; Age at diagnosis: 54.8 years (20,008 days); AJCC staging edition: 8th; AJCC clinical stage: Stage III; AJCC pathologic T: TX; AJCC pathologic N: NX; Tumor grade: GX; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Prior treatment: No.
   Treatment given: Treatment type: Chemotherapy; Treatment intent type: Adjuvant; Initial disease status: Residual Disease.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Radiation Therapy, NOS, for residual disease; Surgery, NOS, for initial diagnosis; adjuvant Targeted Molecular Therapy, for residual disease.

Follow-up (2 entries)
- Days to follow up: 605 days (1.7 years); Disease response: Progressive Disease; Progression or recurrence: Yes.
- Follow-up contact recording only the day: day 6.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 110 kg; Height: 172 cm; BMI: 37.2.
- Timepoint category: Follow-up; Comorbidities: Diabetes, NOS; Days to comorbidity: 20 days; Diabetes treatment type: Injected Insulin.
- Timepoint category: Follow-up; Comorbidities: Diabetes, NOS; Days to comorbidity: 20 days; Diabetes treatment type: Biguanide.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol intensity: Occasional Drinker.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (2 samples)
- Sample HCM-CSHL-0728-C25-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-CSHL-0728-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
